Somatic mutation profile of tumor specimen TCGA-RY-A83Y-01A (aliquot TCGA-RY-A83Y-01A-11D-A36O-08) from TCGA case TCGA-RY-A83Y, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 45.1 years (16,470 days).
Specimen TCGA-RY-A83Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8db3ac7-6da1-4600-b781-f787f6d8dc67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RY-A83Y-10A (Blood Derived Normal), aliquot TCGA-RY-A83Y-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6b53995-0beb-4c11-86d6-6b545f091efd

The open-access MAF lists 35 somatic variants for this specimen: 27 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 16, Silent 8, Nonsense Mutation 6, Frame Shift Del 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 34/86 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARHGAP25 | c.1168C>T p.R390* (on ENST00000409202 / NM_001007231.3; = p.R382* on NM_014882.3) | Nonsense Mutation (SNP) | VAF 38/87 reads (44%) | catalogued as rs1236289126, COSV99771875; called by muse, mutect2, varscan2
- ATP5F1B | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.705); catalogued as COSV100008190; called by muse, mutect2, varscan2
- AUTS2 | c.1663A>G p.I555V | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.28); catalogued as rs769402743, COSV100718972; called by muse, mutect2, varscan2
- CDKN2C | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 29/39 reads (74%) | catalogued as COSV99395983; called by muse, mutect2, varscan2
- CHPF2 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs56366346, COSV99223262; called by muse, mutect2, varscan2
- FERMT1 | c.905del p.L302* | Frame Shift Del (DEL) | VAF 37/100 reads (37%) | catalogued as CM040274; called by mutect2, pindel, varscan2
- FUBP1 | c.991C>T p.R331* | Nonsense Mutation (SNP) | VAF 54/74 reads (73%) | catalogued as COSV53926872; called by muse, mutect2, varscan2
- GPAT3 | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as rs746093877, COSV100023186; called by muse, mutect2, varscan2
- HAO2 | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 26/30 reads (87%) | catalogued as rs779930635, COSV58040052; called by muse, mutect2, varscan2
- HIVEP2 | c.4051A>G p.T1351A | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99174827; called by muse, mutect2
- KLHL10 | c.1106T>C p.V369A | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); catalogued as COSV99509610; called by muse, mutect2, varscan2
- MYL5 | c.143G>C p.G48A | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV100424583, COSV100424715; called by muse, mutect2, varscan2
- NIPBL | c.7012del p.A2338Lfs*8 | Frame Shift Del (DEL) | VAF 30/92 reads (33%) | catalogued as COSV99242335; called by mutect2, pindel, varscan2
- NTRK3 | c.1462A>G p.I488V | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV100447668; called by muse, mutect2, varscan2
- PCDHA2 | c.1973C>T p.A658V | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.036); catalogued as COSV65366485; called by muse, mutect2, varscan2
- PLA2G4E | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as rs759986725, COSV68150401; called by muse, mutect2, varscan2
- PYGL | c.1097G>A p.W366* | Nonsense Mutation (SNP) | VAF 28/64 reads (44%) | catalogued as rs1566503418, COSV99368917; called by muse, mutect2, varscan2
- RASGRP1 | c.1629C>A p.N543K | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100172168; called by muse, mutect2, varscan2
- SEMA7A | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.181); catalogued as rs1231449522, COSV99984934; called by muse, mutect2, varscan2
- SMARCD2 | c.898C>T p.L300F | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1213344317, COSV99856563; called by muse, mutect2, varscan2
- TDRD7 | c.752G>A p.G251D | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100795753; called by muse, mutect2, varscan2
- UBE2W | c.119A>G p.D40G | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100708976; called by muse, mutect2, varscan2
- CCT7 | c.665_666insAA p.Y222* | Nonsense Mutation (INS) | VAF 20/65 reads (31%) | called by mutect2, pindel, varscan2
- CIC | c.1620_1630del p.S541Lfs*145 | Frame Shift Del (DEL) | VAF 31/41 reads (76%) | called by mutect2, pindel, varscan2
- KIAA0753 | c.1164_1165del p.S388Rfs*10 | Frame Shift Del (DEL) | VAF 37/121 reads (31%) | called by mutect2, pindel, varscan2
- ZBTB5 | c.1867_1868del p.L623Dfs*15 | Frame Shift Del (DEL) | VAF 30/101 reads (30%) | called by mutect2, pindel, varscan2
- ACSL6 | c.1011C>T p.H337= (on ENST00000379240; = p.H362= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/37 reads (59%) | catalogued as rs373328179; called by muse, mutect2, varscan2
- CASKIN2 | c.2961A>G p.S987= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs1385648282, COSV100050723; called by muse, mutect2, varscan2
- CPXCR1 | c.411A>G p.S137= | Silent (SNP) | VAF 27/37 reads (73%) | catalogued as COSV52161340; called by muse, mutect2, varscan2
- KIF15 | c.3201T>C p.H1067= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV100393105; called by muse, mutect2, varscan2
- KRT75 | c.618G>A p.E206= | Silent (SNP) | VAF 50/123 reads (41%) | catalogued as COSV99359531; called by muse, mutect2, varscan2
- MAN1A1 | c.1377C>T p.I459= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs757838527, COSV63787625; called by muse, mutect2, varscan2
- MAPKBP1 | c.1452G>A p.S484= (on ENST00000456763 / NM_001128608.2; = p.S478= on NM_014994.3) | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs143874014; called by muse, mutect2, varscan2
- PCDH7 | c.2274G>A p.V758= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs1021908460; called by muse, varscan2
